Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3727, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3727-01A (Primary Tumor).

Diagnosis:

- 1.: Soft tissue shows inflammatory, chronic resorptive cell lesions with pseudocyst formation (possibly so-called oil cysts)
- 2.: Rectosigmoidal resection material includes foci of poorly differentiated adenocarcinoma of the colorectal type 3 cm from the aboral resection margin and measuring a maximum of 4 cm in diameter, with infiltration of the pericolic fatty tissue, marked carcinomatous lymphangiosis accompanying the tumor and two regional lymph node metastases. Tumor-free colon resection margins and tumor-free mesenteric resection margin.

Tumor stage: pT3 pN1 (2/25) pMX; G3, L1, V0, R0

Source: NCI Genomic Data Commons file e0acadb6-d6f6-4421-bc7b-061a68888bfe (TCGA-AG-3727.E5FD008A-5A70-4DC8-8E5B-558946CFD6E4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).